Somatic mutation profile of tumor specimen TCGA-FG-8186-01A (aliquot TCGA-FG-8186-01A-11D-2253-08) from TCGA case TCGA-FG-8186, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 42.2 years (15,431 days).
Specimen TCGA-FG-8186-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36cd9329-89a1-40a1-9793-5a7aca6a73ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8186-10A (Blood Derived Normal), aliquot TCGA-FG-8186-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60e5bff4-1b99-4ff3-a9dd-602ed9114a07

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH1A1 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.077); catalogued as COSV52788997, COSV52791647; called by muse, mutect2, varscan2
- CDKN3 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs749611270, COSV53593199; called by muse, mutect2, varscan2
- CFAP47 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400616865, COSV52885073; called by muse, mutect2, varscan2
- CFAP47 | c.2480C>A p.T827N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV52880480; called by muse, mutect2, varscan2
- CLDN16 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762831659, COSV53227188; called by muse, mutect2, varscan2
- CLMN | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as COSV54182638; called by muse, mutect2, varscan2
- DBX2 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773942722, COSV60337910; called by muse, mutect2
- DDX3X | c.476T>C p.F159S (on ENST00000399959; = p.F160S on NM_001356.5) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863640; called by muse, mutect2
- DPY19L1 | c.1777A>T p.S593C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60582462; called by muse, mutect2, varscan2
- FNBP4 | c.1639A>G p.N547D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV55448870; called by muse, mutect2, varscan2
- GGT6 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs772922247, COSV54598034; called by muse, mutect2, varscan2
- GRIA3 | c.2324+2T>A p.X775_splice | Splice Site (SNP) | VAF 11/146 reads (8%) | catalogued as COSV52061448; called by muse, mutect2
- GUCY1A1 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as rs1464652418, COSV56651988; called by muse, mutect2, varscan2
- HDC | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs777905414, COSV51070898, COSV51074991; called by muse, mutect2, varscan2
- NOL4 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs746858981, COSV52347867; called by muse, mutect2, varscan2
- NOTCH1 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53030917, COSV53042420; called by muse, mutect2
- PCF11 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53531599; called by muse, mutect2, varscan2
- PHF3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as COSV50319971; called by muse, mutect2, varscan2
- SETMAR | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.237); catalogued as rs573824448, COSV62780931; called by muse, mutect2, varscan2
- TSPAN33 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 149/357 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as rs766383285, COSV56826515; called by muse, mutect2, varscan2
- AMER3 | c.2064C>T p.N688= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs763951703, COSV58467051; called by muse, mutect2, varscan2
- CCDC70 | c.57G>A p.A19= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs112168960, COSV54430335, COSV99665404; called by muse, mutect2, varscan2
- LOXL4 | c.1917C>T p.A639= | Silent (SNP) | VAF 28/287 reads (10%) | catalogued as rs1243513600, COSV53256896; called by muse, mutect2, varscan2
- RNF17 | c.3462G>A p.Q1154= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV55041201; called by muse, mutect2, varscan2
- TMEM185A | c.756C>T p.L252= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- BIRC8 | n.1523G>A | RNA (SNP) | VAF 4/72 reads (6%) | catalogued as COSV58843602; called by muse, mutect2
